Somatic mutation profile of tumor specimen BA2932D (aliquot aq-BA2932D) from BEATAML1.0 case 2069, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 29.6 years (10,813 days).
Specimen BA2932D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b430c4-a41f-43af-9440-0f75808ab30e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2015D (Solid Tissue Normal), aliquot aq-BA2015D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/598ad90d-982a-4ff0-9f62-9d42d9798152

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH5 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.046); called by muse, mutect2
- EIF2D | c.528G>T p.L176F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ESPNL | c.2380C>A p.L794M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FAAP100 | c.2186G>T p.C729F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2
- PCDHB7 | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2
- TLN1 | c.7011G>T p.E2337D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2
- CLUAP1 | c.345C>A p.G115= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- DCAF10 | c.447T>C p.T149= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- KIAA0232 | c.-2T>G | 5'UTR (SNP) | VAF 9/88 reads (10%) | called by mutect2, varscan2
